Somatic mutation profile of tumor specimen TCGA-25-1319-01A (aliquot TCGA-25-1319-01A-01D-0452-01) from TCGA case TCGA-25-1319, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.3 years (26,786 days).
Specimen TCGA-25-1319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7bb16bf-971f-4df5-ad00-2792c1981e86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1319-10A (Blood Derived Normal), aliquot TCGA-25-1319-10A-01D-0452-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca36658-2535-40ac-8e1c-1b6b3743ee60

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 51, Silent 12, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 28/30 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55661582; called by muse, mutect2, varscan2
- ARHGAP21 | c.4849G>A p.D1617N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV57604106; called by muse, mutect2, varscan2
- ARID2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV57600386; called by muse, mutect2, varscan2
- ARMCX1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as COSV65705008; called by muse, mutect2, varscan2
- CALCR | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs544410123, COSV64006936; called by muse, mutect2, varscan2
- CDH17 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as COSV50326778; called by muse, mutect2, varscan2
- CHMP4B | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54136211, COSV99459866; called by muse, mutect2, varscan2
- CORO1B | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58168670; called by muse, mutect2, varscan2
- DEPDC1B | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV54008970, COSV54009271; called by muse, mutect2, varscan2
- DNAJC11 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99602306; called by muse, mutect2
- EFHC2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1423278359, COSV101375492; called by muse, mutect2
- GNAL | c.700G>A p.V234I (on ENST00000269162 / NM_001142339.3; = p.V311I on NM_182978.4) | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as CM165376, COSV52333987; called by muse, mutect2, varscan2
- GRK3 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767010348, COSV60793388; called by muse, mutect2, varscan2
- HK3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV52838340; called by muse, mutect2, varscan2
- INHBA | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749989847, COSV54220498; called by muse, mutect2, varscan2
- INSYN2A | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779113272, COSV54734671; called by muse, mutect2, varscan2
- KCNH7 | c.1409T>G p.F470C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59791986; called by muse, mutect2, varscan2
- L2HGDH | c.808A>G p.S270G | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV55556723; called by muse, mutect2, varscan2
- LYST | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV67705375; called by muse, mutect2, varscan2
- MAGEB4 | c.787A>C p.S263R | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66775524; called by muse, mutect2, varscan2
- MALT1 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs564979419, COSV61935200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL13 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100085501; called by muse, mutect2, varscan2
- MRPL13 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100085504; called by muse, mutect2, varscan2
- MYBPC2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100731557; called by muse, mutect2, varscan2
- NDUFB9 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV52674605; called by muse, mutect2
- NEXN | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | catalogued as COSV53942443; called by muse, mutect2, varscan2
- OR10H2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs549916970, COSV59946004; called by muse, mutect2, varscan2
- OR10K1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148047665; called by muse, mutect2, varscan2
- OR2A12 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68821194; called by muse, mutect2, varscan2
- OSBPL2 | c.298C>T p.P100S (on ENST00000313733 / NM_144498.4; = p.P88S on NM_014835.4) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58215983; called by muse, mutect2, varscan2
- PCDH10 | c.2213T>G p.V738G | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV52090601; called by muse, mutect2, varscan2
- PCDHGB6 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53921168; called by muse, mutect2, varscan2
- PCNX1 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs373015087, COSV53095227; called by muse, mutect2, varscan2
- PLXNA3 | c.5168G>A p.R1723H | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63753606; called by muse, varscan2
- PRDM9 | c.2480C>G p.T827R | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV57004441; called by muse, varscan2
- PTCHD3 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1351637148, COSV71256494; called by muse, mutect2, varscan2
- RAPH1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as COSV55582731; called by muse, mutect2, varscan2
- RBMXL1 | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV53099714; called by muse, mutect2, varscan2
- RYR1 | c.10916C>T p.T3639M | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs369390137; called by muse, mutect2
- SCN9A | c.4061C>A p.T1354K (on ENST00000303354; = p.T1343K on NM_002977.3) | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV57605071; called by muse, varscan2
- SETD5 | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56709173; called by muse, mutect2, varscan2
- SNRK | c.1159G>T p.V387F | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.271); catalogued as COSV56067076; called by muse, mutect2, varscan2
- SPIN4 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV58737859; called by muse, mutect2, varscan2
- SRSF1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 147/161 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV51964546; called by muse, mutect2, varscan2
- STAT6 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.411); catalogued as rs780257871, COSV55670051; called by muse, mutect2, varscan2
- TDRD9 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 57/95 reads (60%) | catalogued as rs377183290, COSV59144770; called by muse, mutect2, varscan2
- TMC2 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs778718713, COSV62651135; called by muse, mutect2, varscan2
- TMEM69 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV63432287; called by muse, mutect2, varscan2
- TPCN1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010154228, COSV59233922; called by muse, mutect2, varscan2
- TRPM7 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV57915115; called by muse, mutect2, varscan2
- TTLL4 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV51435659; called by muse, mutect2, varscan2
- YTHDC1 | c.1723C>T p.R575* (on ENST00000344157 / NM_001031732.4; = p.R557* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV60009563; called by muse, mutect2, varscan2
- ZIC1 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99292041; called by muse, mutect2, varscan2
- IGHV3-38 | c.199G>C p.V67L | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ADAMTS19 | c.2787C>T p.S929= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV50738210; called by muse, mutect2, varscan2
- BICRAL | c.1939C>T p.L647= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV58404484; called by muse, mutect2, varscan2
- CAPN10 | c.1230G>A p.A410= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs758982958, COSV54375573; called by muse, mutect2, varscan2
- FLG | c.10203G>T p.G3401= | Silent (SNP) | VAF 94/452 reads (21%) | catalogued as COSV64245638; called by muse, mutect2, varscan2
- KATNIP | c.1470G>A p.S490= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs375213710, COSV55176860; ClinVar: likely benign; called by muse, mutect2, varscan2
- NSF | c.1080C>T p.G360= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs745925224, COSV99833885; called by muse, mutect2, varscan2
- RELN | c.6963G>A p.T2321= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs577520481, COSV58993873; called by muse, mutect2, varscan2
- SDK1 | c.2148G>T p.V716= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1470036071, COSV67358089; called by muse, mutect2, varscan2
- SPDL1 | c.1113T>G p.L371= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs772753899, COSV54667568; called by muse, mutect2, varscan2
- TIPARP | c.1434C>T p.Y478= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV55813603; called by muse, mutect2, varscan2
- TRERF1 | c.1863G>A p.S621= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs148325036; called by muse, mutect2, varscan2
- ZFHX4 | c.7392G>A p.S2464= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs761611371, COSV50650716, COSV50683357; called by muse, mutect2
